Somatic mutation profile of tumor specimen TCGA-13-1510-01A (aliquot TCGA-13-1510-01A-02D-0472-01) from TCGA case TCGA-13-1510, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.2 years (22,708 days).
Specimen TCGA-13-1510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2be4fd96-1153-4c49-bbcb-a874a97400fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1510-10A (Blood Derived Normal), aliquot TCGA-13-1510-10A-01W-0546-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a2573a7-54e9-46da-830a-299eea4e9312

The open-access MAF lists 139 somatic variants for this specimen: 103 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 28, Frame Shift Del 6, Splice Site 5, Intron 5, Nonsense Mutation 4, Frame Shift Ins 2, 3'UTR 2, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 93/118 reads (79%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACD | c.283C>G p.L95V (on ENST00000620338; = p.L9V on NM_022914.3) | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54670486; called by muse, mutect2, varscan2
- ADCY3 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.091); catalogued as COSV53172852; called by muse, mutect2, varscan2
- ALOX15 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 78/91 reads (86%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.572); catalogued as COSV53400751; called by muse, mutect2, varscan2
- ANKRD12 | c.3359T>C p.I1120T | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100042124, COSV50849688; called by muse, mutect2, varscan2
- ANKRD27 | c.1855C>G p.L619V | Missense Mutation (SNP) | VAF 110/400 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60136082; called by muse, mutect2, varscan2
- AP3B2 | c.2880C>T p.C960= (on ENST00000261722; = p.C954= on NM_004644.5) | Splice Region (SNP) | VAF 50/112 reads (45%) | catalogued as COSV55614498; called by muse, mutect2, varscan2
- BDKRB1 | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53707320; called by muse, mutect2, varscan2
- BEND3 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs782458566, COSV64680151; called by muse, mutect2, varscan2
- BRD9 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60250263; called by muse, mutect2, varscan2
- C1orf112 | c.2051C>G p.A684G | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1302468905, COSV53682748; called by muse, mutect2, varscan2
- CADPS | c.2162T>A p.V721D | Missense Mutation (SNP) | VAF 48/492 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51903390; called by muse, mutect2, varscan2
- CD80 | c.674T>A p.V225E | Missense Mutation (SNP) | VAF 139/381 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51803501; called by muse, mutect2, varscan2
- CDH20 | c.179G>C p.S60T | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV53018206; called by muse, mutect2, varscan2
- CDK17 | c.934C>G p.R312G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54132672, COSV54133265; called by muse, mutect2, varscan2
- CELSR3 | c.6703G>T p.A2235S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.028); catalogued as COSV51153140; called by muse, mutect2
- CFAP61 | c.2450A>T p.E817V | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.698); catalogued as COSV55647767; called by muse, mutect2, varscan2
- CILP2 | c.3319C>A p.P1107T | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV52280605; called by muse, mutect2, varscan2
- CNPY1 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV58788836; called by muse, mutect2, varscan2
- CNTNAP4 | c.2144C>G p.S715C | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56689645; called by muse, mutect2
- COL23A1 | c.1494+1G>T p.X498_splice | Splice Site (SNP) | VAF 14/77 reads (18%) | catalogued as COSV66798830; called by muse, mutect2, varscan2
- DCAF12L2 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 125/160 reads (78%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV63580332, COSV63584187; called by muse, mutect2, varscan2
- DROSHA | c.2786A>T p.D929V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV60782860; called by muse, mutect2, varscan2
- EDARADD | c.382A>C p.K128Q (on ENST00000334232 / NM_145861.4; = p.K118Q on NM_080738.4) | Missense Mutation (SNP) | VAF 114/237 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62065200; called by muse, mutect2, varscan2
- EPYC | c.781C>G p.R261G | Missense Mutation (SNP) | VAF 127/313 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99664717; called by muse, mutect2, varscan2
- FABP3 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV65500842; called by muse, mutect2, varscan2
- FLVCR1 | c.797A>C p.D266A | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV65324448; called by muse, mutect2, varscan2
- FNBP4 | c.2057T>C p.L686P | Missense Mutation (SNP) | VAF 70/160 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV55452324; called by muse, mutect2, varscan2
- GLB1 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1407323946; called by muse, mutect2
- GLI1 | c.1941C>A p.D647E | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.197); catalogued as COSV57367576; called by muse, mutect2, varscan2
- GON4L | c.6311C>G p.S2104* | Nonsense Mutation (SNP) | VAF 26/199 reads (13%) | catalogued as COSV55204401; called by muse, mutect2, varscan2
- GPR149 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67670204; called by muse, mutect2, varscan2
- IL10RA | c.504G>C p.E168D | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV57142179, COSV99922916; called by muse, mutect2, varscan2
- IMPDH1 | c.763G>A p.D255N (on ENST00000470772 / NM_001142573.2; = p.D341N on NM_000883.4) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58318058; called by muse, mutect2
- IRAG2 | c.3791A>T p.N1264I (on ENST00000636465; = p.N309I on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63140903; called by muse, mutect2, varscan2
- KIAA0408 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV64108751; called by muse, mutect2, varscan2
- KIF21A | c.3821C>T p.S1274F (on ENST00000361418 / NM_001378440.1; = p.S1261F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV62778203; called by muse, mutect2, varscan2
- LRP4 | c.4766A>G p.N1589S | Missense Mutation (SNP) | VAF 135/350 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV66138714; called by muse, mutect2, varscan2
- MBD4 | c.1019A>G p.K340R | Missense Mutation (SNP) | VAF 63/188 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs372593697; called by muse, mutect2, varscan2
- ME3 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 259/574 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100041914, COSV60164267; called by muse, mutect2, varscan2
- MINAR1 | c.1606G>T p.V536L | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV59586700; called by muse, mutect2, varscan2
- MKLN1 | c.2011G>C p.D671H | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61762877; called by muse, mutect2, varscan2
- MROH5 | c.3495C>A p.H1165Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV61472853; called by muse, mutect2, varscan2
- MS4A6A | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60622016; called by muse, mutect2, varscan2
- MYH4 | c.5697G>T p.K1899N | Missense Mutation (SNP) | VAF 139/167 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1476455445, COSV55126444; called by muse, mutect2, varscan2
- MYT1 | c.1727A>G p.E576G | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60513754; called by muse, mutect2, varscan2
- NDST1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs770655306, COSV55790952; called by muse, mutect2, varscan2
- NEURL1 | c.219G>C p.Q73H | Missense Mutation (SNP) | VAF 99/115 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV63915531; called by muse, mutect2, varscan2
- NLRC5 | c.4327G>C p.A1443P | Missense Mutation (SNP) | VAF 56/344 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV52663265; called by muse, mutect2, varscan2
- P2RY12 | c.693G>T p.R231S | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV56397675; called by muse, mutect2, varscan2
- PCDHGB1 | c.962_964del p.G321del | In Frame Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs1324886463; called by pindel, varscan2
- PGM2L1 | c.1821G>C p.E607D | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV53349848; called by muse, mutect2, varscan2
- PHACTR3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as rs143288140, COSV63027760; called by muse, mutect2, varscan2
- PIK3C2A | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56407068; called by muse, mutect2, varscan2
- PLB1 | c.2175G>C p.L725F | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV59835790; called by muse, mutect2, varscan2
- POMC | c.132+2T>G p.X44_splice | Splice Site (SNP) | VAF 148/405 reads (37%) | catalogued as COSV53035753; called by muse, varscan2
- PTGR1 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 213/601 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV53030926; called by muse, mutect2, varscan2
- RANBP10 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58161315; called by muse, mutect2, varscan2
- RBM47 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55943539; called by muse, mutect2, varscan2
- RIOK3 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV59775176; called by muse, mutect2, varscan2
- RORA | c.222G>C p.K74N (on ENST00000335670 / NM_134261.3; = p.K99N on NM_002943.3) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55044672; called by muse, mutect2, varscan2
- SACS | c.3054G>C p.E1018D | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV66546840; called by muse, mutect2, varscan2
- SCN7A | c.1370C>G p.T457S | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs1319126400; called by muse, mutect2
- SF3A1 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 209/445 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53171378; called by muse, mutect2, varscan2
- SHOC2 | c.187G>C p.G63R | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs1564714645; ClinVar: uncertain significance; called by muse, mutect2
- SLC12A8 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103046, COSV58870741; called by muse, mutect2, varscan2
- SLC24A1 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1457090112; called by muse, mutect2
- SLITRK1 | c.1551G>T p.Q517H | Missense Mutation (SNP) | VAF 135/153 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV65677643; called by muse, mutect2, varscan2
- SNAI1 | c.144G>C p.E48D | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV54865054; called by muse, mutect2, varscan2
- SPARC | c.529A>T p.T177S | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV50560694; called by muse, mutect2, varscan2
- SPR | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1382316466, COSV52298578; called by muse, mutect2, varscan2
- TENT5C | c.317A>T p.Q106L | Missense Mutation (SNP) | VAF 79/308 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV65617154; called by muse, mutect2, varscan2
- TICRR | c.3550G>A p.E1184K | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as COSV51547053; called by muse, mutect2, varscan2
- TNFAIP3 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV52802204, COSV99397445; called by muse, mutect2, varscan2
- TNIK | c.2605C>A p.P869T | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV52696474; called by muse, mutect2, varscan2
- TRPM6 | c.4891A>G p.K1631E | Missense Mutation (SNP) | VAF 88/223 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV62522780; called by muse, mutect2, varscan2
- TRPM7 | c.4280C>G p.S1427C | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs747529375, COSV57921625; called by muse, mutect2, varscan2
- VPS41 | c.1128+1G>A p.X376_splice | Splice Site (SNP) | VAF 9/88 reads (10%) | catalogued as COSV59653307; called by muse, mutect2, varscan2
- WDR88 | c.754A>T p.R252W | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV63452768; called by muse, mutect2, varscan2
- XPOT | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs765829252, COSV60348377; called by muse, varscan2
- ZMYND15 | c.2033G>C p.R678T (on ENST00000433935 / NM_001136046.3; = p.R639T on NM_032265.2) | Missense Mutation (SNP) | VAF 122/139 reads (88%) | SIFT tolerated (0.52); PolyPhen benign (0.26); catalogued as COSV52643741; called by muse, mutect2, varscan2
- ZNF10 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.913); catalogued as rs769085550, COSV50214185; called by muse, mutect2, varscan2
- ZNF121 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 75/238 reads (32%) | catalogued as COSV57552473; called by muse, mutect2, varscan2
- ZNF345 | c.764A>T p.E255V | Missense Mutation (SNP) | VAF 62/80 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV59325308; called by muse, mutect2, varscan2
- ZNF687 | c.2295-1G>A p.X765_splice | Splice Site (SNP) | VAF 8/150 reads (5%) | catalogued as COSV99649186, COSV99650225; called by muse, mutect2
- BCL11A | c.66dup p.E23* | Frame Shift Ins (INS) | VAF 22/82 reads (27%) | called by mutect2, pindel, varscan2
- ECHDC3 | c.839T>G p.L280R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- ELFN2 | c.564C>G p.N188K | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAP | c.1620-37_1620-1del p.X540_splice | Splice Site (DEL) | VAF 96/166 reads (58%) | called by mutect2, pindel
- FGD5 | c.1634del p.T545Ifs*32 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel*, varscan2
- FLNB | c.1889G>A p.S630N | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FSD2 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 11/337 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- GSTCD | c.1568_1592del p.V523Gfs*38 (on ENST00000360505 / NM_001031720.3; = p.V436Gfs*38 on NM_024751.3) | Frame Shift Del (DEL) | VAF 60/117 reads (51%) | called by mutect2, pindel, varscan2
- KIAA0753 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- KLHL13 | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); called by muse, varscan2
- PHF3 | c.1132A>T p.K378* | Nonsense Mutation (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- RFTN1 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 362/1109 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- SBNO1 | c.1811_1847del p.L604* (on ENST00000420886; = p.L603* on NM_018183.5) | Frame Shift Del (DEL) | VAF 72/362 reads (20%) | called by mutect2, pindel
- SND1 | c.2654C>A p.A885D | Missense Mutation (SNP) | VAF 205/481 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM43 | c.537_543del p.I179Mfs*18 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
- UTP3 | c.27_39del p.A10Qfs*19 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- ZNF503 | c.166_187del p.F56Lfs*15 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel
- ZNF510 | c.514dup p.M172Nfs*17 | Frame Shift Ins (INS) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- ABCA12 | c.3567A>C p.P1189= (on ENST00000272895 / NM_173076.3; = p.P871= on NM_015657.3) | Silent (SNP) | VAF 64/248 reads (26%) | catalogued as COSV99787632; called by muse, varscan2
- ALMS1 | c.642G>T p.L214= | Silent (SNP) | VAF 78/190 reads (41%) | catalogued as COSV52522292; called by muse, mutect2, varscan2
- C11orf80 | c.1002T>C p.H334= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs779472496, COSV60931371; called by muse, mutect2, varscan2
- COL16A1 | c.471C>A p.I157= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as rs759580749; called by muse, mutect2, varscan2
- DNAH7 | c.6219T>C p.Y2073= | Silent (SNP) | VAF 66/178 reads (37%) | catalogued as COSV56786762; called by muse, mutect2, varscan2
- FAM222B | c.750C>A p.P250= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV57934118; called by muse, mutect2, varscan2
- FAT2 | c.9072A>T p.V3024= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as COSV55829666; called by muse, mutect2, varscan2
- FGB | c.540A>G p.Q180= | Silent (SNP) | VAF 62/142 reads (44%) | catalogued as rs747127658, COSV57419631; called by muse, mutect2, varscan2
- FGFRL1 | c.282C>T p.A94= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs558236459, COSV53259768; called by muse, mutect2, varscan2
- GRIN2B | c.390C>A p.S130= | Silent (SNP) | VAF 53/444 reads (12%) | catalogued as COSV74207910; called by muse, mutect2, varscan2
- KLHDC1 | c.675C>T p.H225= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs1042754895, COSV63779324; called by muse, mutect2, varscan2
- LMX1B | c.681C>A p.T227= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV62741975; called by muse, mutect2, varscan2
- MAP2 | c.234G>A p.E78= | Silent (SNP) | VAF 83/206 reads (40%) | catalogued as COSV52308226; called by muse, mutect2, varscan2
- MRE11 | c.597A>T p.T199= | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV60580400; called by muse, mutect2, varscan2
- OLFM2 | c.1011C>G p.T337= | Silent (SNP) | VAF 180/619 reads (29%) | catalogued as COSV53433568; called by muse, mutect2, varscan2
- PPP1R3A | c.1239A>T p.G413= | Silent (SNP) | VAF 70/416 reads (17%) | catalogued as COSV52893318; called by muse, mutect2, varscan2
- PRAMEF1 | c.759A>T p.G253= | Silent (SNP) | VAF 255/296 reads (86%) | catalogued as COSV60018714; called by muse, mutect2, varscan2
- RBM6 | c.2106C>G p.G702= | Silent (SNP) | VAF 133/469 reads (28%) | catalogued as COSV56488118; called by muse, mutect2, varscan2
- RRBP1 | c.15C>T p.D5= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV55708937; called by muse, mutect2
- SH3RF3 | c.768C>T p.H256= | Silent (SNP) | VAF 52/88 reads (59%) | catalogued as rs377473947; called by muse, mutect2, varscan2
- SLC39A4 | c.1857C>T p.L619= (on ENST00000301305 / NM_001374839.1; = p.L594= on NM_017767.3) | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV52781516; called by muse, mutect2, varscan2
- SQLE | c.9T>A p.T3= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV56282654; called by muse, mutect2, varscan2
- SRRM2 | c.1662T>A p.S554= | Silent (SNP) | VAF 54/330 reads (16%) | catalogued as COSV57080604; called by muse, mutect2, varscan2
- TBC1D10B | c.927C>T p.F309= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs768634161, COSV69505564; called by muse, varscan2
- TIMELESS | c.829C>A p.R277= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV57508974, COSV57515293; called by muse, mutect2, varscan2
- TIMM44 | c.1119C>T p.D373= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs774364066, COSV54494698; called by muse, mutect2, varscan2
- TYK2 | c.1398C>T p.P466= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs200752112; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- WDR20 | c.1242T>C p.N414= | Silent (SNP) | VAF 7/175 reads (4%) | catalogued as rs1403043335; called by muse, mutect2
- KLRA1P | n.684A>G | RNA (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- LEKR1 | c.*1163A>G | 3'UTR (SNP) | VAF 46/131 reads (35%) | catalogued as COSV62964903; called by muse, mutect2, varscan2
- MCF2L | c.369-462C>G | Intron (SNP) | VAF 73/162 reads (45%) | catalogued as COSV100982025; called by muse, mutect2, varscan2
- MICAL3 | c.2241+4660A>G | Intron (SNP) | VAF 68/162 reads (42%) | catalogued as rs771493406, COSV52905512; called by muse, mutect2, varscan2
- OCLN | c.*2A>C | 3'UTR (SNP) | VAF 76/89 reads (85%) | catalogued as rs1295696691, COSV100783736; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.81+89G>C | Intron (SNP) | VAF 185/596 reads (31%) | called by muse, mutect2, varscan2
- SH3TC1 | c.172+280A>T | Intron (SNP) | VAF 15/16 reads (94%) | catalogued as COSV99794215; called by muse, varscan2
- SRSF6 | c.257-602G>C | Intron (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
